Somatic mutation profile of tumor specimen C3N-00491-05 (aliquot CPT0012670006) from CPTAC case C3N-00491, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 54.2 years (19,779 days).
Specimen C3N-00491-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2115f20e-2849-4b0f-ab78-f68d03bb35ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00491-31 (Blood Derived Normal), aliquot CPT0012730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a06429a-7316-4ddb-bcde-1f5c2ae62892

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Frame Shift Del 6, 3'UTR 5, Intron 5, Nonsense Mutation 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX5 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 59/482 reads (12%) | catalogued as rs104894377, CM971436, COSV59858590; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 43/281 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1553619431, CM031392, CM951278, COSV56542744, COSV56546104, COSV56548816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM32 | c.2095G>C p.A699P | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV65948326, COSV65953065; called by muse, mutect2, varscan2
- CAMSAP1 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751192974; called by mutect2, varscan2
- CSN2 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1041678553; called by muse, mutect2, varscan2
- FAM177B | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.901); catalogued as rs376729517; called by muse, mutect2, varscan2
- FBP2 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 31/275 reads (11%) | catalogued as rs376093116; called by muse, mutect2, varscan2
- FERMT1 | c.152-1G>T p.X51_splice | Splice Site (SNP) | VAF 34/190 reads (18%) | catalogued as CX119407, COSV54098016; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2, varscan2
- SLC26A5 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs1234227146, COSV59698327; called by muse, mutect2
- ST6GAL2 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 23/171 reads (13%) | PolyPhen possibly damaging (0.625); catalogued as rs528424981; called by muse, mutect2, varscan2
- UBE2Q1 | c.704del p.K235Rfs*8 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | catalogued as COSV52724218; called by mutect2, pindel, varscan2
- ZCCHC24 | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV64887427; called by muse, mutect2, varscan2
- APPL1 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- C14orf119 | c.148T>A p.S50T | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CEBPZ | c.2731T>G p.F911V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DNAH17 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUSP28 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3B | c.663_664del p.F221Lfs*3 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, pindel
- EPS8L2 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FADS2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAM120AOS | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 35/269 reads (13%) | called by muse, mutect2, varscan2
- FAT2 | c.8150C>T p.A2717V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2
- GALNT15 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- JMJD4 | c.478_479del p.D160Lfs*50 | Frame Shift Del (DEL) | VAF 24/198 reads (12%) | called by pindel, varscan2
- KRTAP4-8 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MICALL1 | c.971G>C p.S324T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBRM1 | c.743T>C p.M248T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, varscan2
- PIGR | c.1915G>C p.A639P | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- PITPNM2 | c.3274A>C p.T1092P | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAB28 | c.443G>C p.C148S | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RAB7A | c.-8-5T>G | Splice Region (SNP) | VAF 103/359 reads (29%) | called by muse, mutect2, varscan2
- SBF1 | c.3135del p.P1046Lfs*59 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- SETD2 | c.6955del p.I2319Lfs*34 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- SFTPB | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SLC35F3 | c.500T>A p.L167Q (on ENST00000366617 / NM_001300845.1; = p.L236Q on NM_173508.4) | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPIN2B | c.339G>T p.R113S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); called by mutect2, varscan2
- THPO | c.563G>A p.S188N (on ENST00000649095 / NM_001290003.1; = p.S48N on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMC2 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USP31 | c.2995G>C p.D999H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WWC3 | c.3022del p.L1008Sfs*39 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- ZBTB21 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, varscan2
- ZNF556 | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CALR3 | c.1080G>A p.E360= | Silent (SNP) | VAF 33/283 reads (12%) | catalogued as rs752458256, COSV54172260; called by muse, mutect2, varscan2
- CLTA | c.129T>A p.I43= | Silent (SNP) | VAF 21/140 reads (15%) | called by muse, mutect2, varscan2
- DLX6 | c.465C>T p.N155= | Silent (SNP) | VAF 40/331 reads (12%) | catalogued as rs754678377, COSV99142483; called by muse, mutect2, varscan2
- FHDC1 | c.3279G>A p.R1093= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- GTF3C1 | c.3972C>G p.V1324= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV62242150; called by muse, varscan2
- LANCL3 | c.594C>A p.I198= | Silent (SNP) | VAF 15/48 reads (31%) | called by mutect2, varscan2
- NACAD | c.4482C>A p.V1494= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2, varscan2
- PIKFYVE | c.5868T>A p.L1956= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- SNX31 | c.24G>A p.P8= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as rs1222778593; called by muse, mutect2
- TMEM168 | c.1701A>G p.Q567= | Silent (SNP) | VAF 37/276 reads (13%) | called by muse, mutect2, varscan2
- VPS13D | c.7041T>G p.A2347= | Silent (SNP) | VAF 36/330 reads (11%) | called by muse, mutect2
- ANK3 | c.1393-21A>G | Intron (SNP) | VAF 36/275 reads (13%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*681T>A | 3'UTR (SNP) | VAF 72/488 reads (15%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2266+5873G>T | Intron (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2
- ORAI3 | c.*242C>A | 3'UTR (SNP) | VAF 30/262 reads (11%) | called by muse, mutect2, varscan2
- PDPK1 | c.24+509C>T | Intron (SNP) | VAF 65/538 reads (12%) | catalogued as rs759476910; called by muse, mutect2, varscan2
- PYGB | c.1828-590A>T | Intron (SNP) | VAF 38/129 reads (29%) | called by muse, mutect2, varscan2
- SRP19 | c.*563del | 3'UTR (DEL) | VAF 30/353 reads (8%) | called by mutect2, pindel
- TMCO1 | c.*2195G>C | 3'UTR (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- VAPB | c.*6473G>C | 3'UTR (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2, varscan2
- ZAP70 | c.402+48A>T | Intron (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
